Gene-level copy-number profile of tumor specimen TCGA-56-8083-01A from TCGA case TCGA-56-8083, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 56.7 years (20,696 days).
Specimen TCGA-56-8083-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.30e9e4a3-3397-41e5-b815-523fb27ec66e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8083-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f997762-df84-4695-8086-4fe3e666a00a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 12,781; copy number 2: 40,111; copy number 3: 4,531; copy number 4: 638; copy number 5: 92; copy number 6: 1,287; copy number 7: 47; copy number 8: 39; copy number 9: 41; copy number 10: 12; copy number 13: 93; copy number 15: 71; copy number 20: 38; copy number 29: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8083-01A-11D-2243-01): tumor purity 0.91, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,496,392–4,635,654, 2 genes: AC010941.1, AC022068.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,755 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,778,148–183,463,201, 626 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr4:43,457,527–44,025,516, 8 genes, copy number 6 (within-gene range 1–6): LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475.
- chr4:44,622,065–45,051,652, 9 genes, copy number 5: YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1.
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (broad region; genes not listed).
- chr7:89,443,946–99,952,158, 202 genes, copy number 13–20 (broad region; genes not listed).
- chr9:33,041,765–34,048,949, 47 genes, copy number 7 (within-gene range 1–7): SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2, PTENP1, PTENP1-AS, TRBV26OR9-2, AL356489.2, AL356489.3, AL356489.1, AL356489.4, LINC01251, PRSS3, UBE2R2-AS1, TRBV29OR9-2, UBE2R2, Y_RNA, RNU4ATAC11P, UBAP2, SNORD121B, SNORD121A, OSTCP8.
- chr9:35,673,918–38,068,687, 77 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr11:68,980,021–71,639,769, 76 genes, copy number 9–29 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,402. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
